Somatic mutation profile of tumor specimen HCM-BROD-0254-C49-86N (aliquot HCM-BROD-0254-C49-86N-01D-A85C-36) from HCMI case HCM-BROD-0254-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 11.9 years (4,358 days).
Specimen HCM-BROD-0254-C49-86N: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 15.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc4f5a4b-61e3-41e5-b0ac-415bc231fa3d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0254-C49-10A (Blood Derived Normal), aliquot HCM-BROD-0254-C49-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6eca083-b0d3-4142-89d7-00cd5377578b

The open-access MAF lists 69 somatic variants for this specimen: 50 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 18, Nonsense Mutation 4, Frame Shift Ins 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARG1 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 18/338 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as COSV99256262; called by muse, mutect2
- ATP10B | c.2097G>T p.L699F | Missense Mutation (SNP) | VAF 168/783 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.105); catalogued as COSV59144042; called by muse, mutect2, varscan2
- CCDC168 | c.14248G>A p.E4750K | Missense Mutation (SNP) | VAF 187/442 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.299); catalogued as COSV104400384; called by muse, mutect2, varscan2
- CHFR | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 43/397 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs776005190; called by muse, mutect2, varscan2
- CTSK | c.16G>A p.V6I | Missense Mutation (SNP) | VAF 130/858 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs201086925; called by muse, mutect2, varscan2
- CYP11B1 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 145/532 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs544670837, COSV52824806, COSV52825753; called by muse, varscan2
- DCDC1 | c.3418C>T p.L1140F (on ENST00000597505 / NM_001367979.1; = p.L247F on NM_020869.3) | Missense Mutation (SNP) | VAF 97/583 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs538219168, COSV60309252; called by muse, mutect2, varscan2
- DKK3 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 40/1102 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs1237582653; called by muse, mutect2
- ITGB1BP1 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 91/464 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs774507175; called by muse, varscan2
- KRT78 | c.301G>T p.D101Y | Missense Mutation (SNP) | VAF 33/527 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58853834; called by muse, mutect2
- LIMD2 | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 113/624 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as rs370859086; called by muse, mutect2, varscan2
- MYH8 | c.1323G>T p.W441C | Missense Mutation (SNP) | VAF 174/1049 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67960594, COSV67966111; called by muse, mutect2, varscan2
- PPM1J | c.754C>A p.R252S | Missense Mutation (SNP) | VAF 46/661 reads (7%) | SIFT tolerated (0.83); PolyPhen benign (0.005); catalogued as COSV100497363; called by muse, mutect2
- TIGD3 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 173/1114 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52891650; called by muse, mutect2, varscan2
- TMEM63B | c.1738G>A p.G580S | Missense Mutation (SNP) | VAF 196/651 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52482334; called by muse, mutect2, varscan2
- UBR5 | c.3626C>T p.T1209M | Missense Mutation (SNP) | VAF 20/332 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764816360, COSV55285081; called by muse, mutect2
- ADH4 | c.1038C>A p.F346L | Missense Mutation (SNP) | VAF 135/365 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ARNT2 | c.182G>A p.S61N | Missense Mutation (SNP) | VAF 62/465 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- CAMK2G | c.1276C>T p.R426* (on ENST00000423381 / NM_001367518.1; = p.R363* on NM_001222.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 127/670 reads (19%) | called by muse, varscan2
- CEACAM19 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 32/498 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DSC3 | c.2013T>A p.C671* | Nonsense Mutation (SNP) | VAF 110/413 reads (27%) | called by muse, mutect2, varscan2
- FAH | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 136/830 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, varscan2
- FOXO3 | c.927_930dup p.S311Pfs*7 | Frame Shift Ins (INS) | VAF 89/388 reads (23%) | called by mutect2, pindel, varscan2
- GRAMD1C | c.401A>T p.K134M | Missense Mutation (SNP) | VAF 67/250 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HLA-DPB1 | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 159/513 reads (31%) | called by muse, mutect2, varscan2
- HYDIN | c.10898C>T p.S3633F | Missense Mutation (SNP) | VAF 33/259 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- KMT2C | c.4898A>T p.Q1633L | Missense Mutation (SNP) | VAF 147/621 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MAB21L4 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 200/877 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- MGA | c.2305A>G p.N769D | Missense Mutation (SNP) | VAF 83/540 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- OR52A5 | c.413T>C p.F138S | Missense Mutation (SNP) | VAF 26/718 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2
- OR5T2 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 106/769 reads (14%) | called by muse, mutect2, varscan2
- OTOF | c.3158C>T p.A1053V (on ENST00000272371 / NM_194248.3; = p.A306V on NM_004802.4) | Missense Mutation (SNP) | VAF 103/578 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCNX3 | c.683G>A p.S228N | Missense Mutation (SNP) | VAF 38/1062 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- PER3 | c.952C>G p.L318V | Missense Mutation (SNP) | VAF 18/390 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- PPM1G | c.1416G>C p.L472F | Missense Mutation (SNP) | VAF 84/483 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRDM14 | c.722C>T p.T241I | Missense Mutation (SNP) | VAF 96/427 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, varscan2
- PRRC2C | c.5552C>T p.T1851I (on ENST00000367742; = p.T1849I on NM_015172.4) | Missense Mutation (SNP) | VAF 73/1518 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2
- RABGAP1L | c.532G>A p.E178K (on ENST00000489615 / NM_001243765.2; = p.E61K on NM_001243764.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/476 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- RELL2 | c.107G>A p.C36Y | Missense Mutation (SNP) | VAF 143/722 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEMA6B | c.2377G>A p.A793T | Missense Mutation (SNP) | VAF 206/810 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SERPINB4 | c.1102C>A p.P368T | Missense Mutation (SNP) | VAF 114/387 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SIRPA | c.464G>A p.G155D | Missense Mutation (SNP) | VAF 95/834 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- SLC45A2 | c.1549A>G p.I517V | Missense Mutation (SNP) | VAF 862/870 reads (99%) | SIFT tolerated (0.15); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SPOCD1 | c.2387G>C p.W796S | Missense Mutation (SNP) | VAF 63/250 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- TLE3 | c.2129A>G p.Y710C | Missense Mutation (SNP) | VAF 75/537 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- TMCC2 | c.1639G>A p.D547N | Missense Mutation (SNP) | VAF 125/636 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- VPS41 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 124/544 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WDR11 | c.1740G>T p.K580N | Missense Mutation (SNP) | VAF 25/308 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ZFYVE9 | c.3906_3909dup p.A1304* | Frame Shift Ins (INS) | VAF 45/223 reads (20%) | called by mutect2, pindel, varscan2
- ZNF90 | c.587C>G p.T196S | Missense Mutation (SNP) | VAF 110/377 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- ADAD2 | c.1176C>A p.G392= (on ENST00000315906 / NM_001145400.2; = p.G474= on NM_139174.4) | Silent (SNP) | VAF 234/891 reads (26%) | called by muse, varscan2
- ADGRL2 | c.3321C>G p.G1107= (on ENST00000370717 / NM_001366005.1; = p.G1094= on NM_012302.4) | Silent (SNP) | VAF 38/473 reads (8%) | called by muse, mutect2
- ALDH1A1 | c.564C>T p.N188= | Silent (SNP) | VAF 100/490 reads (20%) | called by muse, mutect2, varscan2
- CATSPERG | c.2601G>A p.G867= | Silent (SNP) | VAF 111/372 reads (30%) | catalogued as COSV53051110; called by muse, mutect2, varscan2
- CBX6 | c.1053C>T p.S351= | Silent (SNP) | VAF 481/736 reads (65%) | catalogued as rs775494009, COSV99328049; called by muse, mutect2, varscan2
- CD163 | c.2853G>A p.G951= | Silent (SNP) | VAF 36/586 reads (6%) | catalogued as COSV63130905; called by muse, mutect2
- CWC22 | c.1041C>T p.F347= | Silent (SNP) | VAF 90/546 reads (16%) | catalogued as COSV55431689; called by muse, mutect2, varscan2
- ELFN1 | c.2127C>T p.G709= | Silent (SNP) | VAF 255/1204 reads (21%) | called by muse, mutect2, varscan2
- FIBIN | c.300C>T p.G100= | Silent (SNP) | VAF 185/1041 reads (18%) | catalogued as rs1435631368; called by muse, mutect2, varscan2
- OR2L2 | c.888G>T p.V296= | Silent (SNP) | VAF 93/554 reads (17%) | called by muse, varscan2
- PIK3AP1 | c.219G>A p.A73= | Silent (SNP) | VAF 203/869 reads (23%) | catalogued as rs773426752; called by muse, mutect2, varscan2
- PKP3 | c.1896G>A p.L632= | Silent (SNP) | VAF 144/1206 reads (12%) | called by muse, varscan2
- PRKCG | c.1441C>T p.L481= | Silent (SNP) | VAF 13/401 reads (3%) | catalogued as rs1568760422; called by muse, mutect2
- SHROOM4 | c.2880G>A p.R960= | Silent (SNP) | VAF 32/335 reads (10%) | catalogued as COSV56787871; called by muse, mutect2, varscan2
- SLC23A3 | c.987C>T p.T329= | Silent (SNP) | VAF 147/924 reads (16%) | called by muse, mutect2, varscan2
- THSD7A | c.507G>A p.A169= | Silent (SNP) | VAF 174/688 reads (25%) | catalogued as rs867019373, COSV101448676; called by muse, varscan2
- TNFSF11 | c.249C>A p.G83= | Silent (SNP) | VAF 18/277 reads (6%) | called by muse, mutect2
- WDR87 | c.6921G>A p.E2307= | Silent (SNP) | VAF 93/565 reads (16%) | catalogued as COSV58206457; called by muse, mutect2, varscan2
- MGAM | c.4618+8628C>A | Intron (SNP) | VAF 57/427 reads (13%) | called by muse, mutect2, varscan2
